Surgical pathology report (de-identified scan), TCGA case TCGA-49-AARR, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-AARR-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

[REDACTED]

=====

INTERPRETATION AND DIAGNOSIS:

1. LEFT LUNG, UPPER LOBE (LOBECTOMY): INFILTRATING MODERATELY DIFFERENTIATED ADENOCARCINOMA (3 CM). INFILTRATING CARCINOMA EXTENDS TO WITHIN 1 MM OF THE INKED PLEURAL MARGIN BUT THE MARGIN IS MICROSCOPICALLY NEGATIVE. BRONCHIAL, VASCULAR, AND THE PARENCHYMAL MARGINS OF RESECTION ARE NEGATIVE FOR TUMOR. EIGHT (8) HILAR LYMPH NODES, NEGATIVE FOR TUMOR. NON NEOPLASTIC LUNG WITH CENTRIOBULAR EMPHYSEMA AND DUST MACULES. SEE NOTE.

NOTE: The pathologic stage is T1N0MX.

2. LYMPH NODE, STATION 5 (EXCISION): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

*Electronic signature

=====

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Lung, upper lobe C84.1

Q 5/20/14

[page 2 of 3]
PART #1: FS: LEFT UPPER LOBE
Resident Pathologist:

FROZEN SECTION BY:

FROZEN SECTION DIAGNOSIS: LEFT UPPER LOBE: NON-SMALL CELL CARCINOMA,
3 CM.

The specimen is received fresh labeled [REDACTED] designated "Left upper lobe". It consists of a grossly recognizable partial pneumonectomy specimen measuring 22 x 13 x 5 cm. There is a firm palpable nodule that is inferior to the hilar bronchi and vessels. Sectioning through the pulmonary parenchyma reveals a 2 x 3 x 1.5 cm tan-white mass. A frozen section diagnosis was performed on this specimen. There is a row of staples in the inferior aspect of the specimen. This row of staples measures 6 cm. The specimen weighs 210 grams following tissue harvest of segments of the apex and base of the specimen. On the lateral aspect of the lung there is puckering of the pleural surface. This measures 1.2 x 1 cm. The mass is located beneath the puckering and appears to approach the inked margin. The tumor measures approximately 2 cm from the staple margin, and approximately 3 cm from the hilar bronchi and vessels. The mass measures approximately 1 cm from the pleural surface on the medial aspect of the lung. The non-neoplastic lung parenchyma is stained with anthracotic pigment, but is otherwise unremarkable. Representative sections of the specimen are submitted. Approximately 2% of the specimen is submitted for sectioning.

SUMMARY OF SECTIONS

- 1 - A - 4 (A SHAVE OF VASCULAR AND BRONCHIAL MARGINS)
- 3 - B-D - 2 (BISECTED LYMPH NODES)
- 1 - E - 3 (LYMPH NODES)
- 4 - F-I - (REPRESENTATIVE SECTIONS OF TUMOR AT INKED MARGIN)
- 1 - J - MULTIPLE (A SHAVE OF STAPLE MARGIN)
- 2 - K, L - 2 EACH (PERPENDICULAR SECTIONS FROM STAPLE MARGIN)
- 2 - M, N - 1 EACH (NORMAL LUNG)
- 1 - FSC - 1 (FROZEN SECTION OF TUMOR)
- 15 - TOTAL - MULTIPLE

(Continued on next page.)

[page 3 of 3]
PART #2: STATION 5 LYMPH NODE
Resident Pathologist:

Dictated by

The specimen is received fresh labeled [REDACTED] and is designated as station 5 lymph node. It consists of a single piece of soft tissue, dark brown to pink tan and gray, measuring 0.7 x 0.4 x 0.2 cm. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

1 - A - 1
1 - TOTAL - 1

Other Surgical Pathology Specimens known to the computer: [REDACTED]

(End of Report)

printed

Criteria	11/18/14	Yes	No

Source: NCI Genomic Data Commons file 2f588612-a953-410c-abec-f8628fd0eef9 (TCGA-49-AARR.55998E02-5285-4E6F-8BB8-7DB57F18C0D2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).